Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A5QQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A5QQ-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous
(Carcinoma, metaplastic)
8575/3

Site C66F (B) Breast NOS
path (B) Breast, central
position C50.1
JW 4/2/13

A. Breast, right, simple mastectomy: Moderately differentiated squamous carcinoma (metaplastic carcinoma) involving the mammary parenchyma forming a 5.2 x 5.0 x 4.7 cm mass located in the central aspect of the breast with skin ulceration. Angiolymphatic invasion is present. The surrounding breast parenchyma shows nonproliferative fibrocystic changes. A single (of 3) intramammary lymph node is positive for metastatic carcinoma forming a solid and cystic mass (6.5 x 5.0 x 4.7 cm) located in the lateral aspect of the breast. Extranodal extension is present. The skin and nipple areolar region is involved by tumor. All surgical resection margins, including skin and deep margins, are negative for tumor (minimum tumor free margin, 1.7 cm, deep margin).

Estrogen receptor, progesterone receptor, and HER2 will be performed and reported in an addendum.

B. Lymph nodes, right axillary, excision: Multiple (21) lymph nodes are negative for metastatic carcinoma.

With available surgical materials, [AJCC pT3N1] (7th edition, 2010).

Seen in consultation with

Source: NCI Genomic Data Commons file b2926547-f514-441d-8729-4e76c9ced1b1 (TCGA-AR-A5QQ.511282C5-02AC-4105-8B52-5BBEC8B45D22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).